Somatic mutation profile of tumor specimen TCGA-HD-A6HZ-01A (aliquot TCGA-HD-A6HZ-01A-12D-A31L-08) from TCGA case TCGA-HD-A6HZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 79.5 years (29,045 days).
Specimen TCGA-HD-A6HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fefc9976-66ed-4489-8c8b-bd4c4e3d0b73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-A6HZ-10A (Blood Derived Normal), aliquot TCGA-HD-A6HZ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06bdf64f-b6a8-4b1f-bd57-c5278bb86827

The open-access MAF lists 91 somatic variants for this specimen: 62 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 27, Nonsense Mutation 10, Frame Shift Del 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF4 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1264445313, COSV51956425, COSV99348000; called by muse, mutect2, varscan2
- AHNAK2 | c.14135C>T p.S4712F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100315461; called by muse, mutect2, varscan2
- AHNAK2 | c.11065C>T p.Q3689* | Nonsense Mutation (SNP) | VAF 30/328 reads (9%) | catalogued as COSV100315462; called by muse, mutect2
- AHNAK2 | c.8306C>T p.A2769V | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs550119106, COSV100315464; called by muse, mutect2, varscan2
- AHNAK2 | c.8305G>T p.A2769S | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100315466; called by muse, mutect2, varscan2
- AHNAK2 | c.7160C>A p.P2387Q | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100315472; called by muse, mutect2, varscan2
- AHNAK2 | c.6403C>A p.L2135M | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV60915041; called by muse, mutect2, varscan2
- AHNAK2 | c.1562C>G p.S521* | Nonsense Mutation (SNP) | VAF 24/158 reads (15%) | catalogued as COSV100315480; called by muse, mutect2
- APBB1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs144723218; called by muse, mutect2, varscan2
- ARHGEF15 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV62725486; called by muse, mutect2, varscan2
- ATP2B3 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1416640986, COSV99682911; called by muse, mutect2, varscan2
- C2orf73 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100471219; called by muse, mutect2, varscan2
- CCNE1 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99388169; called by muse, mutect2, varscan2
- CD93 | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs891369060, COSV55665567; called by muse, mutect2
- COL27A1 | c.2891G>A p.G964D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61928873; called by muse, mutect2, varscan2
- DGKK | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 61/336 reads (18%) | catalogued as COSV101052874; called by muse, mutect2, varscan2
- DHX16 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100906041; called by muse, mutect2, varscan2
- DYRK3 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs200713840, COSV65606409; called by muse, mutect2, varscan2
- EP300 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99607261; called by muse, mutect2, varscan2
- ESRP2 | c.1547G>A p.R516Q (on ENST00000565858 / NM_001365264.1; = p.R506Q on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.993); catalogued as rs745503556, COSV99251069; called by mutect2, varscan2
- FN1 | c.1169C>A p.S390* | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | catalogued as COSV100115858, COSV60547906; called by muse, mutect2, varscan2
- FOXJ2 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV99368069; called by muse, mutect2, varscan2
- GNB4 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1560216452, COSV51708754; called by muse, mutect2, varscan2
- GPR39 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100257013; called by muse, mutect2
- GRIA2 | c.2615G>A p.G872D | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99642951; called by muse, mutect2
- GRIN3B | c.1739G>C p.G580A | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99312184; called by muse, mutect2
- HMGXB4 | c.1458G>C p.M486I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53335669, COSV99329897; called by muse, mutect2, varscan2
- HOXA7 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV99636220; called by muse, mutect2, varscan2
- HSPG2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 29/188 reads (15%) | catalogued as COSV101012883; called by muse, mutect2, varscan2
- KCTD13 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100441592; called by muse, mutect2, varscan2
- KIAA1109 | c.9689G>T p.G3230V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV99145715; called by muse, mutect2
- KREMEN2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.505); catalogued as COSV99566772; called by muse, mutect2, varscan2
- LGSN | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as rs775519999, COSV65726818; called by mutect2, varscan2
- LRP1B | c.13739A>C p.D4580A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV101252202; called by muse, mutect2, varscan2
- MED12L | c.2153C>G p.S718C | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56370529, COSV99851455; called by muse, mutect2, varscan2
- NFE2L2 | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV101229295; called by muse, mutect2, varscan2
- NKTR | c.3630G>T p.K1210N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV99235140; called by muse, mutect2, varscan2
- PAX1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs1415574372, COSV68271656; called by muse, mutect2, varscan2
- PCDHB2 | c.256T>A p.L86M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99522785; called by muse, mutect2, varscan2
- PROCA1 | c.412G>A p.E138K (on ENST00000439862 / NM_001366301.1; = p.E110K on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99972500; called by muse, mutect2
- ROS1 | c.5356C>T p.L1786F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63851731; called by muse, mutect2, varscan2
- SEC16A | c.4948G>A p.A1650T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99256062; called by muse, mutect2, varscan2
- SGK2 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as COSV100414548; called by muse, mutect2
- SIGLEC10 | c.1505G>A p.W502* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV100218455; called by muse, mutect2, varscan2
- SLC18A3 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.301); catalogued as rs1258597013, COSV60329136; called by muse, mutect2, varscan2
- SLC26A3 | c.2029A>T p.I677F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100384808; called by muse, mutect2, varscan2
- SLC38A10 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777202842, COSV99917128; called by muse, mutect2, varscan2
- SLC5A7 | c.1445T>A p.L482H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV99886195; called by muse, mutect2
- SLIT2 | c.2468G>T p.G823V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99880712; called by muse, mutect2, varscan2
- SMG8 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99958665; called by muse, mutect2
- SUPT20H | c.769C>T p.P257S (on ENST00000350612 / NM_001014286.3; = p.P258S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100634530; called by muse, mutect2, varscan2
- TRAPPC11 | c.1595C>G p.S532C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100591651; called by muse, mutect2, varscan2
- UBR7 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99184171; called by muse, mutect2, varscan2
- USP16 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100537785; called by muse, mutect2, varscan2
- ZNF536 | c.2258G>A p.C753Y | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100834635, COSV62834544; called by muse, mutect2, varscan2
- ZNF91 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100322136, COSV56083428; called by muse, mutect2, varscan2
- CCSER1 | c.357del p.F119Lfs*9 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- DOT1L | c.2889_2910del p.T964Lfs*97 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel
- EIF4E3 | c.475G>A p.D159N (on ENST00000425534 / NM_001134651.2; = p.D53N on NM_173359.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAV8-6 | c.62A>C p.Q21P | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS3 | c.345G>C p.L115= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV99710148; called by muse, mutect2, varscan2
- AHNAK2 | c.15750C>A p.L5250= | Silent (SNP) | VAF 57/346 reads (16%) | catalogued as COSV100315457; called by muse, mutect2, varscan2
- AHNAK2 | c.7743C>T p.L2581= | Silent (SNP) | VAF 40/339 reads (12%) | catalogued as COSV100315469; called by muse, mutect2, varscan2
- AHNAK2 | c.2628C>T p.L876= | Silent (SNP) | VAF 45/400 reads (11%) | catalogued as COSV100315475, COSV60912516; called by muse, mutect2, varscan2
- ARHGEF6 | c.102G>A p.S34= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as rs749558536, COSV99166347; called by muse, mutect2, varscan2
- EDAR | c.381G>C p.P127= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs1231995132, COSV99303029; called by muse, mutect2
- EPS15 | c.2325C>T p.I775= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs766207505, COSV100869402; called by muse, mutect2, varscan2
- GRIP1 | c.150C>T p.G50= | Silent (SNP) | VAF 42/758 reads (6%) | catalogued as rs1383535458, COSV54026606, COSV99670854; called by muse, mutect2
- GRM3 | c.2622C>A p.S874= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV100862077; called by muse, mutect2
- IGHA2 | c.30G>A p.P10= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as rs1288871461; called by muse, mutect2, varscan2
- KAT2A | c.1533G>A p.K511= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99287985; called by muse, mutect2, varscan2
- KRT39 | c.555C>T p.Y185= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs761258011, COSV62917276; called by muse, mutect2
- MKRN3 | c.90G>A p.P30= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs746453158, COSV58809613; called by muse, mutect2, varscan2
- NCOA1 | c.4083G>A p.L1361= | Silent (SNP) | VAF 37/330 reads (11%) | catalogued as COSV99945173; called by muse, mutect2, varscan2
- NDST3 | c.1260G>T p.V420= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99629561; called by muse, mutect2, varscan2
- OR2T27 | c.855C>G p.L285= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV61282647, COSV61283261; called by muse, mutect2, varscan2
- OR6C68 | c.918T>A p.I306= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1565703507, COSV101110008; called by muse, mutect2, varscan2
- PGLYRP2 | c.1317G>A p.T439= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs147572500; called by muse, mutect2, varscan2
- SIK2 | c.2202T>C p.F734= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV100231836; called by muse, mutect2, varscan2
- SLC18A1 | c.1272G>A p.S424= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs377170157; called by muse, mutect2, varscan2
- SPIB | c.180C>A p.A60= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as COSV99569764; called by muse, mutect2
- STPG4 | c.207G>A p.V69= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs1201773493, COSV99681185; called by muse, mutect2, varscan2
- TLR9 | c.2610C>T p.Y870= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as rs201959275, COSV62348687; called by muse, mutect2, varscan2
- TSTD2 | c.366A>C p.S122= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV100358947; called by muse, mutect2, varscan2
- USP30 | c.885G>A p.T295= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs771270733, COSV57448102; called by muse, mutect2, varscan2
- ZNF292 | c.4929T>G p.A1643= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100369726; called by muse, mutect2, varscan2
- ZNF318 | c.1710G>C p.L570= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV100545936; called by muse, mutect2, varscan2
- DCHS2 | n.1826G>A | RNA (SNP) | VAF 6/48 reads (13%) | catalogued as rs765671963, COSV100250831; called by mutect2, varscan2
- LDB3 | c.896+6765C>T | Intron (SNP) | VAF 18/127 reads (14%) | catalogued as COSV99554706; called by muse, mutect2, varscan2
